Gene-level copy-number profile of tumor specimen TCGA-49-4487-01A from TCGA case TCGA-49-4487, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.8 years (26,583 days).
Specimen TCGA-49-4487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5aede5d3-228b-450a-b42a-8b834cd18bc9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4487-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a60e507-c96d-4889-aac8-3348b1571128

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,466; copy number 2: 27,206; copy number 3: 18,332; copy number 4: 6,030; copy number 5: 2,558; copy number 6: 899; copy number 7: 20; copy number 8: 60; copy number 9: 166; copy number 16: 81.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4487-01A-21D-1854-01): tumor purity 0.17, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,784 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–164,980,137, 899 genes, copy number 6 (broad region; genes not listed).
- chr3:87,594,838–91,513,775, 27 genes, copy number 9: APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr6:167,607–25,452,263, 419 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:25,287,432–25,287,533, 1 gene, copy number 5: Y_RNA.
- chr6:81,813,286–105,083,332, 247 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–43,617,904, 723 genes, copy number 5 (broad region; genes not listed).
- chr10:43,630,882–43,648,881, 5 genes, copy number 5: AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2.
- chr14:21,653,835–47,675,605, 564 genes, copy number 5–16 (within-gene range 2–16) (broad region; genes not listed).
- chr18:11,326,270–12,725,740, 60 genes, copy number 8: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2.
- chr18:62,187,255–80,247,514, 259 genes, copy number 5 (broad region; genes not listed).
- chr19:32,390,050–37,614,179, 247 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr19:39,125,770–45,305,284, 333 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,544. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
